Somatic mutation profile of tumor specimen C3L-02176-01 (aliquot CPT0100470008) from CPTAC case C3L-02176, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 79.2 years (28,912 days).
Specimen C3L-02176-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1770b968-e027-488b-9d1f-18d59a8b3d5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02176-31 (Blood Derived Normal), aliquot CPT0101950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00986e81-8c67-4d5a-9cfe-f41d6110d7a6

The open-access MAF lists 91 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 21, Frame Shift Del 10, Intron 8, Frame Shift Ins 2, Nonsense Mutation 2, 3'UTR 2, Splice Region 1, 5'UTR 1, Splice Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7A | c.336T>G p.N112K | Missense Mutation (SNP) | VAF 69/278 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as rs148963985; called by muse, mutect2, varscan2
- ANKIB1 | c.3211G>A p.V1071I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1304396458; called by muse, mutect2, varscan2
- CSF1 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60035170; called by muse, mutect2, varscan2
- DYSF | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs566595009, COSV50342784; called by muse, mutect2, varscan2
- ECD | c.887del p.R296Qfs*7 | Frame Shift Del (DEL) | VAF 35/175 reads (20%) | catalogued as COSV100881325; called by mutect2, pindel, varscan2
- ERGIC1 | c.663C>A p.H221Q | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs1464836104; called by muse, mutect2, varscan2
- FAM83G | c.1746A>T p.E582D | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV58760390; called by muse, mutect2, varscan2
- HBP1 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs1457929042; called by muse, mutect2, varscan2
- LARP4B | c.2080C>T p.R694W | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs775911921; called by muse, mutect2, varscan2
- LIPI | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.024); catalogued as rs764811231; called by muse, mutect2, varscan2
- NDUFA9 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1262086539; called by muse, mutect2, varscan2
- PALB2 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs1060502733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RB1CC1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1166022062; called by muse, mutect2, varscan2
- SEC31B | c.2678G>A p.G893E | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as rs374745319; called by muse, mutect2, varscan2
- VHL | c.233dup p.N78Kfs*54 | Frame Shift Ins (INS) | VAF 74/282 reads (26%) | catalogued as COSV56560515; called by mutect2, pindel, varscan2
- WDR47 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs776604885; called by muse, mutect2, varscan2
- ACOT8 | c.809G>C p.W270S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP17A | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKAR | c.630C>G p.D210E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ARID1B | c.2614C>T p.Q872* | Nonsense Mutation (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- ATP13A2 | c.347+7C>T | Splice Region (SNP) | VAF 54/223 reads (24%) | called by muse, mutect2, varscan2
- BICRA | c.912del p.S305Lfs*38 | Frame Shift Del (DEL) | VAF 30/113 reads (27%) | called by mutect2, pindel, varscan2
- CASP10 | c.964C>T p.H322Y (on ENST00000272879 / NM_032974.5; = p.H279Y on NM_001230.5) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CD81 | c.460-1G>A p.X154_splice | Splice Site (SNP) | VAF 88/429 reads (21%) | called by muse, mutect2, varscan2
- CDYL | c.1358G>A p.G453E (on ENST00000328908 / NM_001368125.1; = p.G399E on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEND1 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CNKSR2 | c.2591C>T p.A864V | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, varscan2
- CRTC2 | c.134T>G p.M45R | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CRYL1 | c.99_100del p.K33Nfs*3 | Frame Shift Del (DEL) | VAF 23/171 reads (13%) | called by mutect2, pindel, varscan2
- DMXL2 | c.7793A>C p.N2598T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- GPC3 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 64/318 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, varscan2
- HNRNPC | c.667A>T p.K223* (on ENST00000420743; = p.K210* on NM_004500.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- INVS | c.1474G>C p.A492P | Missense Mutation (SNP) | VAF 25/340 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.804); called by muse, mutect2
- KAT6A | c.3552del p.Q1185Kfs*109 | Frame Shift Del (DEL) | VAF 62/357 reads (17%) | called by mutect2, pindel, varscan2
- LIPE | c.1620del p.A541Pfs*22 | Frame Shift Del (DEL) | VAF 41/204 reads (20%) | called by mutect2, pindel, varscan2
- LIPI | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MEIOB | c.418_426del p.I140_L142del | In Frame Del (DEL) | VAF 18/173 reads (10%) | called by mutect2, pindel
- MTMR4 | c.2987T>C p.V996A | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP10 | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOC2L | c.243del p.E82Sfs*14 | Frame Shift Del (DEL) | VAF 42/227 reads (19%) | called by mutect2, pindel, varscan2
- NUDC | c.100_109del p.S34Dfs*71 | Frame Shift Del (DEL) | VAF 62/413 reads (15%) | called by mutect2, pindel, varscan2
- OR5AP2 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- PANK4 | c.1996C>A p.L666I | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PHKA1 | c.1963C>G p.R655G | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POP1 | c.1796del p.L599* | Frame Shift Del (DEL) | VAF 72/327 reads (22%) | called by mutect2, pindel, varscan2
- PRDM2 | c.527A>C p.Q176P | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- RFWD3 | c.837G>A p.M279I | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN4A | c.590A>G p.D197G | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN7A | c.90_91insTT p.E31Lfs*9 | Frame Shift Ins (INS) | VAF 25/209 reads (12%) | called by mutect2, pindel, varscan2
- SETD1A | c.1687del p.R563Gfs*98 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- SLC39A9 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, varscan2
- SRSF7 | c.360T>G p.H120Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT5A | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WLS | c.738del p.F246Lfs*13 | Frame Shift Del (DEL) | VAF 53/249 reads (21%) | called by mutect2, pindel, varscan2
- ZNF292 | c.6038A>C p.E2013A | Missense Mutation (SNP) | VAF 50/203 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF732 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- ZNF736 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 49/251 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- ABHD4 | c.198C>T p.N66= | Silent (SNP) | VAF 48/341 reads (14%) | catalogued as rs546341661, COSV53529438; called by muse, mutect2, varscan2
- ACVR1B | c.858G>A p.E286= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as rs749000887; called by muse, mutect2, varscan2
- ANXA11 | c.822C>T p.V274= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs768032954; called by muse, mutect2, varscan2
- CTDP1 | c.1530A>T p.A510= | Silent (SNP) | VAF 56/197 reads (28%) | called by muse, mutect2, varscan2
- FKBP9 | c.1005C>T p.V335= | Silent (SNP) | VAF 60/194 reads (31%) | catalogued as COSV54229513; called by muse, mutect2, varscan2
- GASK1B | c.798G>A p.G266= | Silent (SNP) | VAF 86/409 reads (21%) | called by muse, mutect2, varscan2
- ITPR1 | c.6708A>G p.Q2236= (on ENST00000354582; = p.Q2181= on NM_002222.7) | Silent (SNP) | VAF 56/223 reads (25%) | called by muse, mutect2, varscan2
- LRRC8B | c.2161C>T p.L721= | Silent (SNP) | VAF 32/158 reads (20%) | called by muse, varscan2
- MUC17 | c.34C>T p.L12= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- NCSTN | c.1492C>T p.L498= | Silent (SNP) | VAF 126/462 reads (27%) | called by muse, mutect2, varscan2
- NDRG1 | c.1107G>A p.G369= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs577399876; called by muse, mutect2, varscan2
- NES | c.882C>A p.S294= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- OR2L13 | c.438C>T p.G146= | Silent (SNP) | VAF 81/387 reads (21%) | called by muse, mutect2, varscan2
- PATJ | c.3018T>C p.A1006= | Silent (SNP) | VAF 33/162 reads (20%) | called by muse, mutect2, varscan2
- PBRM1 | c.666A>C p.A222= | Silent (SNP) | VAF 20/120 reads (17%) | called by muse, varscan2
- S1PR2 | c.504T>C p.L168= | Silent (SNP) | VAF 44/177 reads (25%) | called by muse, mutect2, varscan2
- SCN9A | c.576T>C p.D192= | Silent (SNP) | VAF 18/338 reads (5%) | catalogued as rs762966087; ClinVar: likely benign; called by muse, mutect2
- SLC7A11 | c.1158C>T p.D386= | Silent (SNP) | VAF 43/189 reads (23%) | catalogued as COSV99763618; called by muse, mutect2, varscan2
- SPANXN5 | c.108C>T p.L36= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as rs781966903; called by muse, mutect2, varscan2
- TKT | c.1746C>A p.I582= | Silent (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- ZNF418 | c.885T>C p.F295= | Silent (SNP) | VAF 65/251 reads (26%) | called by muse, varscan2
- CEBPE | c.*8del | 3'UTR (DEL) | VAF 38/204 reads (19%) | called by mutect2, pindel, varscan2
- DLL1 | c.*29T>A | 3'UTR (SNP) | VAF 70/270 reads (26%) | called by muse, mutect2, varscan2
- GSTO2 | c.-83dup | 5'UTR (INS) | VAF 47/172 reads (27%) | called by mutect2, pindel, varscan2
- MPPED2 | c.311-9275T>A | Intron (SNP) | VAF 35/209 reads (17%) | called by muse, mutect2, varscan2
- PPP2R2B | c.1052+880G>A | Intron (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- PRR12 | c.52-169T>A | Intron (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- RNU6-341P | chr14:58291698 C>T | 3'Flank (SNP) | VAF 21/87 reads (24%) | catalogued as rs551911065; called by muse, mutect2, varscan2
- RPUSD1 | c.511+141A>C | Intron (SNP) | VAF 58/292 reads (20%) | called by muse, mutect2, varscan2
- SLC16A5 | c.-48-126C>A | Intron (SNP) | VAF 30/199 reads (15%) | called by muse, mutect2, varscan2
- SSH2 | c.107+32711A>G | Intron (SNP) | VAF 34/164 reads (21%) | catalogued as rs933278692; called by muse, mutect2, varscan2
- TIMP1 | c.329-30T>C | Intron (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- ULK3 | c.103-226G>T | Intron (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439146 G>T | 5'Flank (SNP) | VAF 40/136 reads (29%) | catalogued as rs768076115; called by muse, mutect2, varscan2
